Somatic mutation profile of tumor specimen TCGA-S9-A6U6-01A (aliquot TCGA-S9-A6U6-01A-12D-A33T-08) from TCGA case TCGA-S9-A6U6, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 28.1 years (10,253 days).
Specimen TCGA-S9-A6U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 162b8532-868c-4eae-bbe2-3295ed744c0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U6-10A (Blood Derived Normal), aliquot TCGA-S9-A6U6-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a3c4c2e-f9a7-4607-a930-d93dc1c4d79e

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 26, Silent 4, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 76/212 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 48/55 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANGPT4 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs894721531, COSV101124744; called by muse, mutect2, varscan2
- ANKRD29 | c.627+1G>A p.X209_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99409182; called by muse, mutect2
- BICRAL | c.2887C>G p.H963D | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV100018126; called by muse, mutect2
- BSG | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100344794; called by muse, mutect2, varscan2
- CASP2 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV100131017; called by muse, mutect2
- COMP | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1164785187, COSV55876431; called by muse, mutect2, varscan2
- FOLH1 | c.1499A>G p.K500R | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV99923284; called by muse, mutect2, varscan2
- GCN1 | c.6892G>A p.A2298T | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs774344398, COSV100325352; called by muse, mutect2, varscan2
- GRIA4 | c.883A>G p.K295E | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as rs1176642973, COSV99231891; called by muse, mutect2, varscan2
- GRIN2A | c.3329C>T p.S1110L | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100409997; called by muse, mutect2, varscan2
- HMCN1 | c.14731A>T p.K4911* | Nonsense Mutation (SNP) | VAF 41/149 reads (28%) | catalogued as COSV99629904; called by muse, mutect2, varscan2
- KLF6 | c.243A>G p.I81M | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV99435068; called by muse, mutect2
- LRRC32 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99476982; called by muse, mutect2, varscan2
- NRSN2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as rs773224878, COSV101206800; called by muse, mutect2, varscan2
- RNF25 | c.911T>G p.L304W | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV99829029; called by muse, mutect2, varscan2
- RPN1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759305274, COSV56189900; called by muse, mutect2, varscan2
- RUBCNL | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100529107; called by muse, mutect2, varscan2
- RUSC2 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100770733; called by muse, mutect2, varscan2
- SLC27A2 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99982868; called by muse, mutect2, varscan2
- SMC1B | c.2660T>C p.V887A | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV100663272; called by muse, mutect2
- SPEF2 | c.1614G>T p.R538S | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV100607582; called by muse, mutect2
- TBC1D31 | c.3052G>C p.D1018H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99782789; called by muse, mutect2
- TOP1MT | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV61317428; called by muse, mutect2, varscan2
- TTN | c.33014C>T p.P11005L (on ENST00000591111; = p.P10078L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/197 reads (16%) | PolyPhen benign (0); catalogued as rs539800132, COSV59947474; called by muse, mutect2, varscan2
- USH1C | c.1439T>G p.V480G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140166; called by muse, mutect2, varscan2
- WHRN | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99470311; called by muse, mutect2, varscan2
- ATRX | c.3993dup p.K1332* | Frame Shift Ins (INS) | VAF 46/87 reads (53%) | called by pindel, varscan2
- AHR | c.2253A>T p.G751= | Silent (SNP) | VAF 47/295 reads (16%) | catalogued as COSV99619760; called by muse, mutect2, varscan2
- GNAS | c.1335G>A p.A445= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1442429952, COSV100005875; called by mutect2, varscan2
- IDO2 | c.408G>A p.T136= (on ENST00000389060; = p.T149= on NM_194294.2) | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1209430412, COSV58426368; called by muse, mutect2, varscan2
- MTSS1 | c.280A>C p.R94= | Silent (SNP) | VAF 21/224 reads (9%) | catalogued as COSV100274956; called by muse, mutect2
